FM case AD16189 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Primary site: Other and unspecified urinary organs.
https://portal.gdc.cancer.gov/cases/9c273b68-2d89-4c96-90e7-d4517a73cef8

Female, 55.8 years: diagnosis not reported by GDC of the urinary system; metastasis biopsied or resected from the bladder. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Metastatic.
